Somatic mutation profile of tumor specimen C3N-02950-02 (aliquot CPT0240910006) from CPTAC case C3N-02950, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.6 years (26,507 days).
Specimen C3N-02950-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d68033c-5316-488b-89ec-1d21c96a213b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02950-31 (Blood Derived Normal), aliquot CPT0241780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b145766-9f65-45c2-872c-c16a013ed46d

The open-access MAF lists 116 somatic variants for this specimen: 86 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 23, Nonsense Mutation 8, Intron 4, Splice Region 4, 5'UTR 2, Splice Site 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 134/507 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ANGPTL1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs1260671370; called by muse, mutect2, varscan2
- ANKMY2 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as COSV100187223; called by muse, mutect2, varscan2
- ATL2 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755842865; called by muse, mutect2, varscan2
- CASP4 | c.902T>G p.I301S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67745005; called by muse, varscan2
- CDC42 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59661980; called by muse, mutect2, varscan2
- CFAP36 | c.1013A>T p.E338V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752098505; called by muse, mutect2, varscan2
- COL6A3 | c.7375C>T p.R2459W | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371066956, COSV55088845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DBX2 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 42/463 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.104); catalogued as rs377508330; called by muse, mutect2
- DCAF8L2 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 92/303 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs777879257; called by muse, mutect2, varscan2
- FAT3 | c.7880C>T p.P2627L | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs766693054, COSV53091995; called by muse, mutect2, varscan2
- FER1L6 | c.3673C>T p.Q1225* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV67552003; called by muse, mutect2, varscan2
- FNIP1 | c.2116T>C p.W706R | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.225); catalogued as rs781161480; called by muse, mutect2, varscan2
- FSCB | c.1400C>A p.A467E | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as rs961681691; called by muse, mutect2, varscan2
- GDAP1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM1410962; called by muse, mutect2, varscan2
- HTR1E | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1263006902, COSV59506673; called by muse, mutect2, varscan2
- IMPDH1 | c.307G>A p.E103K (on ENST00000470772 / NM_001142573.2; = p.E188K on NM_000883.4) | Missense Mutation (SNP) | VAF 87/578 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV58315552; called by muse, mutect2, varscan2
- KIF3C | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs752763278; called by muse, mutect2, varscan2
- LGI3 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs780300477; called by muse, mutect2, varscan2
- LRRC15 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.226); catalogued as rs757264988, COSV61650262; called by muse, mutect2, varscan2
- MORC1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 19/181 reads (10%) | catalogued as COSV51714995, COSV51722623; called by muse, mutect2, varscan2
- MTBP | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1382965811; called by muse, mutect2, varscan2
- MUC16 | c.26987C>T p.S8996L | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV67496862; called by muse, mutect2, varscan2
- PAQR9 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.024); catalogued as COSV61418605; called by muse, mutect2, varscan2
- PCDHA5 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 75/629 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782806803, COSV65353370; called by muse, mutect2, varscan2
- PLPPR4 | c.1328G>C p.R443P | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100926791, COSV64568024; called by muse, mutect2
- PRELID3B | c.202-4T>G | Splice Region (SNP) | VAF 88/228 reads (39%) | catalogued as rs753552797; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277254399; called by muse, mutect2
- RABEP2 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs770945536; called by muse, mutect2, varscan2
- SLC9A2 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 83/473 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1204114848; called by muse, mutect2, varscan2
- SSTR1 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57455357; called by muse, mutect2, varscan2
- STAC3 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 134/463 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs767857119; called by muse, mutect2, varscan2
- TMEM117 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 25/354 reads (7%) | catalogued as COSV56908543; called by muse, mutect2
- TNR | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs545364805, COSV99689217; called by muse, mutect2, varscan2
- TNXB | c.9551C>T p.P3184L (on ENST00000647633; = p.P2937L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV100925694; called by muse, mutect2
- WASF2 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs146728512; called by muse, mutect2
- ZFHX4 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99264875; called by muse, mutect2, varscan2
- ZNF431 | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs867216454, COSV60674692; called by muse, mutect2, varscan2
- ACHE | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP7A | c.1751C>G p.S584C | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASZ1 | c.1105A>C p.K369Q | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CHP2 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CHST13 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNTRL | c.4066A>G p.M1356V | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A3 | c.4712C>T p.P1571L | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.5134C>G p.L1712V | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DLGAP2 | c.2579G>A p.R860K | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ELOVL4 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ETV6 | c.1036T>A p.Y346N | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F8 | c.5230G>T p.G1744C | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- FAT4 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 80/231 reads (35%) | called by muse, mutect2, varscan2
- GOT1 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- GRID1 | c.1829G>C p.W610S | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HUWE1 | c.9247G>A p.A3083T | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- IGHV3-23 | c.169del p.R57Afs*27 | Frame Shift Del (DEL) | VAF 130/573 reads (23%) | called by mutect2, pindel, varscan2
- JAK1 | c.2358C>G p.I786M | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHFPL4 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K12 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MYO5A | c.986T>A p.L329H | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAA60 | c.*207-3C>T | Splice Region (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- NDUFV1 | c.155+8A>T | Splice Region (SNP) | VAF 223/685 reads (33%) | called by muse, mutect2, varscan2
- OR9A2 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHKA1 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIF1 | c.1547T>C p.F516S | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L1 | c.5237G>C p.S1746T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- POGZ | c.2642C>T p.T881I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRSS38 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 41/311 reads (13%) | called by muse, mutect2, varscan2
- RB1CC1 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBBP7 | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SATB2 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 99/550 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMCR8 | c.1124_1129del p.F375_E377delins* | Nonsense Mutation (DEL) | VAF 47/151 reads (31%) | called by mutect2, pindel, varscan2
- SORL1 | c.3050-1G>C p.X1017_splice | Splice Site (SNP) | VAF 33/96 reads (34%) | called by muse, varscan2
- SOS2 | c.2680A>G p.R894G | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SREK1IP1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SRP54 | c.429G>A p.G143= | Splice Region (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 20/260 reads (8%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- SV2C | c.1574T>G p.V525G | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TIGD6 | c.1271A>T p.D424V | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TMEM82 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRIM9 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC24 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- UVSSA | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 105/252 reads (42%) | called by muse, mutect2, varscan2
- VCPIP1 | c.3124G>C p.D1042H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- VCPKMT | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF181 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2
- ZNF90 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARID5A | c.354G>A p.L118= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- BRD1 | c.2703C>T p.Y901= (on ENST00000216267 / NM_001349940.1; = p.Y1032= on NM_001304808.3) | Silent (SNP) | VAF 77/260 reads (30%) | catalogued as rs370621351; called by muse, mutect2, varscan2
- CACNA1S | c.1227G>A p.Q409= | Silent (SNP) | VAF 26/231 reads (11%) | called by mutect2, varscan2
- CHFR | c.1023C>T p.T341= (on ENST00000432561 / NM_001161345.1; = p.T300= on NM_018223.2) | Silent (SNP) | VAF 77/261 reads (30%) | called by muse, mutect2, varscan2
- CHST4 | c.444C>A p.P148= | Silent (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- DGKZ | c.12G>T p.R4= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2, varscan2
- DNAI2 | c.87C>T p.I29= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as rs768747332, COSV56757692; called by muse, mutect2
- ERLIN2 | c.663G>C p.V221= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- FLG | c.4146C>A p.V1382= | Silent (SNP) | VAF 225/780 reads (29%) | called by muse, mutect2, varscan2
- FN1 | c.486T>C p.G162= | Silent (SNP) | VAF 58/330 reads (18%) | called by muse, mutect2, varscan2
- KALRN | c.7941C>T p.P2647= (on ENST00000360013 / NM_001024660.4; = p.P950= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/168 reads (30%) | catalogued as rs750693702; called by muse, mutect2, varscan2
- MYH2 | c.5211G>A p.E1737= | Silent (SNP) | VAF 48/262 reads (18%) | called by muse, mutect2, varscan2
- OR4S2 | c.105C>T p.I35= | Silent (SNP) | VAF 76/283 reads (27%) | catalogued as COSV100412862; called by muse, mutect2, varscan2
- OTOGL | c.6321G>A p.Q2107= (on ENST00000547103; = p.Q2098= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- PFKFB2 | c.948G>C p.V316= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs768903592; called by muse, mutect2, varscan2
- PTCH1 | c.3183G>A p.A1061= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs878853854, COSV59474253; ClinVar: likely benign; called by muse, mutect2, varscan2
- RB1CC1 | c.4531C>T p.L1511= | Silent (SNP) | VAF 65/215 reads (30%) | catalogued as COSV50256154; called by muse, mutect2, varscan2
- RHOXF1 | c.474T>C p.C158= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- SALL1 | c.1674G>A p.P558= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs747355231, COSV51760174; called by muse, mutect2
- SLC13A1 | c.265C>T p.L89= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs1398009204; called by muse, mutect2
- SLCO2A1 | c.1365C>T p.F455= | Silent (SNP) | VAF 52/255 reads (20%) | called by muse, mutect2, varscan2
- TP53BP2 | c.228A>C p.G76= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- ZAN | c.12A>G p.P4= | Silent (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- C1orf159 | c.553+617C>T | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as rs762195510; called by muse, mutect2, varscan2
- EXPH5 | c.-232C>T | 5'UTR (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- FAXDC2 | c.367-936G>A | Intron (SNP) | VAF 29/152 reads (19%) | catalogued as rs901669862; called by muse, mutect2, varscan2
- FOXO3 | c.-13G>A | 5'UTR (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- HGD | c.176+44A>G | Intron (SNP) | VAF 90/240 reads (38%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77915641 T>A | 3'Flank (SNP) | VAF 62/294 reads (21%) | called by muse, mutect2
- RPS14 | c.388+180A>T | Intron (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2, varscan2
